Gene-level copy-number profile of tumor specimen TCGA-FV-A4ZQ-01A from TCGA case TCGA-FV-A4ZQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.3 years (19,090 days).
Specimen TCGA-FV-A4ZQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c0486809-32e0-4fae-a69c-05c84478ba9c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FV-A4ZQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82807f18-ed0b-4bb5-8e9e-46cb927d670c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,334; copy number 2: 38,904; copy number 3: 12,521; copy number 4: 3,216; copy number 5: 1,561; copy number 6: 138; copy number 7: 146.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FV-A4ZQ-01A-11D-A25U-01): tumor purity 0.64, ploidy 2.4, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,845 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:109,915,976–110,727,121, 6 genes, copy number 5: NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–7 (broad region; genes not listed).
- chr11:59,636,716–63,410,294, 190 genes, copy number 5–7 (broad region; genes not listed).
- chr11:67,662,160–70,436,584, 91 genes, copy number 5 (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 5: AP001271.1.
- chr11:72,478,221–73,142,318, 23 genes, copy number 7 (within-gene range 2–7): ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1.

Autosomal genes at a single copy (total copy number 1): 947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
